Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A65X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A65X-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localisation: frontal lobe

Diagnosis: anaplastic oligoastrocytoma (grade 3 WHO)

Name of Pathologist:

Oligoastrocytoma,
anaplastic 9882/3
path
Site: Brain, frontal lobe C71.1
C67.5 Brain, supratentorial NOS
C71.0
JW 4/19/13

Source: NCI Genomic Data Commons file d18479be-fae1-434b-9112-9361471a7b4b (TCGA-QH-A65X.D7B970B7-6910-4926-AD60-F24EEFAFE54A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).